MMRF case MMRF_1783 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/fcffb652-dfbf-446b-9cae-fe55eb40ece8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Dead; Days to death: 718 days (2.0 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.9 years (21,139 days); ISS stage: II; Days to last known disease status: 718 days (2.0 years); Days to last follow up: 718 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 11 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 156 days.
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 192 days; Days to treatment end: 380 days (1.0 years).
   Treatment given: Therapeutic agents: Carfilzomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 380 days (1.0 years); Days to treatment end: 481 days (1.3 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 495 days (1.4 years); Days to treatment end: 495 days (1.4 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 632 days (1.7 years); Days to treatment end: 718 days (2.0 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 718.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -32 (ECOG 1): M Protein 2.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 12.3 mg/dL; Immunoglobulin G 3.43 g/L; Immunoglobulin A 22.9 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 3.33 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 3.85 ×10⁹/L; Platelets 397 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 33 g/L; Total Protein 7.6 g/dL; Glucose 7.26 mmol/L.
- Day 65 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.74 mg/dL; Immunoglobulin A 2.31 g/L; Immunoglobulin M 0.333 g/L; Lactate Dehydrogenase 5.1 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 633 ×10⁹/L; Creatinine 108 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 6.6 mmol/L.
- Day 156 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.5 mg/dL; Immunoglobulin G 6.12 g/L; Immunoglobulin A 4.28 g/L; Immunoglobulin M 0.426 g/L; Lactate Dehydrogenase 5.18 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 369 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.15 mmol/L; Albumin 32 g/L; Total Protein 6.8 g/dL; Glucose 7.59 mmol/L.
- Day 225 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 6.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 11.4 mg/dL; Immunoglobulin G 5.55 g/L; Immunoglobulin A 2.56 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 6.53 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.06 ×10⁹/L; Platelets 312 ×10⁹/L; Creatinine 106 µmol/L; Albumin 31 g/L; Total Protein 6.9 g/dL; Glucose 7.37 mmol/L.
- Day 303 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 16.9 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 14.7 mg/dL; Immunoglobulin G 6.44 g/L; Immunoglobulin A 3.51 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 4.22 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 7.31 ×10⁹/L; Absolute Neutrophil 4.79 ×10⁹/L; Platelets 259 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 11.4 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 6.7 g/dL; Glucose 6.22 mmol/L.
- Day 380 (ECOG 2): M Protein 0.59 g/dL; Immunoglobulin A 3.39 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 6.1 ×10⁹/L; Platelets 213 ×10⁹/L.
- Day 523 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.4 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 3.34 g/L; Immunoglobulin M 0.775 g/L; Lactate Dehydrogenase 5.98 µkat/L; Hemoglobin 5.89 mmol/L; Leukocytes 10.5 ×10⁹/L; Absolute Neutrophil 7.2 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.1 mmol/L; Albumin 33 g/L; Total Protein 6.9 g/dL; Glucose 7.76 mmol/L.
- Day 597 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.4 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 3.04 g/L; Immunoglobulin M 0.453 g/L; Lactate Dehydrogenase 3.53 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.48 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 5.89 mmol/L.
- Day 674 (ECOG 2): Hemoglobin 5.7 mmol/L; Leukocytes 7.77 ×10⁹/L; Absolute Neutrophil 4.45 ×10⁹/L; Platelets 238 ×10⁹/L.

Other clinical attributes
- Day -32: Weight: 153 kg; Height: 196 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (3 samples)
- Sample MMRF_1783_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -32 days.
- Sample MMRF_1783_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -32 days.
- Sample MMRF_1783_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 380 days (1.0 years).
